Gene-level copy-number profile of tumor specimen TCGA-CG-4475-01A from TCGA case TCGA-CG-4475, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 76.8 years (28,065 days).
Specimen TCGA-CG-4475-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.2b770435-fa3c-44c4-ba31-2a2d7085beb8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4475-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8f9e956a-f8a4-4dea-913a-0a2818dc7d51

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,537; copy number 2: 16,639; copy number 3: 23,438; copy number 4: 7,654; copy number 5: 6,573; copy number 6: 841; copy number 7: 1,444; copy number 8: 133; copy number 9: 9; copy number 10: 28; copy number 12: 8; copy number 13: 26; copy number 14: 1; copy number 15: 7; copy number 16: 72; copy number 17: 175; copy number 18: 59; copy number 26: 39; copy number 27: 19; copy number 31: 39; copy number 41: 27; copy number 49: 26; copy number 60: 3; copy number 73: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-4475-01A-01D-1155-01): tumor purity 0.43, ploidy 3.02, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,132 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,019,656–147,788,953, 27 genes, copy number 7: AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2.
- chr1:149,754,301–151,993,859, 133 genes, copy number 8 (broad region; genes not listed).
- chr1:153,330,120–155,563,162, 142 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr2:46,816,697–81,201,184, 586 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr2:155,089,439–158,753,775, 46 genes, copy number 49–73: RNU6-1001P, MTCO1P45, MTND2P20, ATP5F1AP2, MTND4P28, MTND5P30, MTND6P9, MTCYBP9, RNU6-546P, AC073225.1, LINC01876, HEBP2P1, AC074099.1, NR4A2, GPD2, LINC01958, RPLP0P7, AC096589.2, AC096589.1, AC108057.1, CDK7P1, GALNT5, RN7SKP281, ERMN, FAM133DP, CYTIP, ACVR1C, AC019186.1, ACVR1, UPP2, AC013731.1, RNU6-436P, AC091488.1, MTA3P1, RNU6-932P, PTP4A1P1, UPP2-IT1, CCDC148-AS1, CCDC148, HNRNPDLP2, RN7SL393P, PKP4, RPL7AP22, PKP4-AS1, AC005042.1, AC005042.2.
- chr4:116,193,997–116,739,945, 9 genes, copy number 7: TTC39CP1, MTRNR2L13, MIR1973, TRMT112P1, CUL4AP1, AC106892.1, ACTN4P1, AC093765.5, AC093765.4.
- chr4:116,754,453–116,921,792, 2 genes, copy number 7 (within-gene range 4–7): AC093765.2, RNU6-119P.
- chr7:90,466,424–91,210,590, 1 gene, copy number 9 (within-gene range 5–15): CDK14.
- chr7:91,030,149–95,615,132, 85 genes, copy number 9–26 (broad region; genes not listed).
- chr8:85,617,344–102,688,906, 313 genes, copy number 7 (broad region; genes not listed).
- chr8:104,330,324–104,467,055, 1 gene, copy number 7 (within-gene range 6–7): DPYS.
- chr8:104,419,512–129,844,504, 291 genes, copy number 7–17 (broad region; genes not listed).
- chr8:129,864,478–129,901,758, 3 genes, copy number 17: AC022973.2, AC022973.1, AC022973.4.
- chr12:62,545,582–76,033,932, 258 genes, copy number 7–41 (within-gene range 2–41) (broad region; genes not listed).
- chr19:27,638,483–31,349,436, 72 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr20:61,717,506–64,313,132, 140 genes, copy number 7 (broad region; genes not listed).
- chr22:29,327,680–29,423,179, 1 gene, copy number 7 (within-gene range 3–7): AP1B1.
- chr22:29,387,909–30,030,868, 22 genes, copy number 7 (within-gene range 4–7): AC002059.3, AC000041.1, RFPL4AP6, RFPL1S, RFPL1, NEFH, AC000035.1, THOC5, AC005529.1, NIPSNAP1, NF2, RPEP4, AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10, ASCC2, MTMR3, RNU6-331P.

Autosomal genes at a single copy (total copy number 1): 2,537. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
